Somatic mutation profile of tumor specimen TCGA-X6-A8C4-01A (aliquot TCGA-X6-A8C4-01A-11D-A36J-09) from TCGA case TCGA-X6-A8C4, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 70.9 years (25,896 days).
Specimen TCGA-X6-A8C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30afda26-0e79-4c20-95c2-9b63e440bef4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A8C4-10A (Blood Derived Normal), aliquot TCGA-X6-A8C4-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fc53f85-544a-43a0-98c5-e7f2e7a9f539

The open-access MAF lists 74 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 56, Silent 14, Splice Site 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- ACHE | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs761313292, COSV99574635; called by muse, mutect2, varscan2
- ACKR1 | c.676T>G p.F226V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100929689, COSV63672855; called by muse, mutect2, varscan2
- ADAMTS18 | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99274443; called by muse, mutect2
- AKAP5 | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100278097; called by muse, mutect2, varscan2
- AP3S2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as rs139910320; called by muse, mutect2, varscan2
- APBA1 | c.2182-1G>C p.X728_splice | Splice Site (SNP) | VAF 10/45 reads (22%) | catalogued as COSV55235655, COSV99597272; called by muse, mutect2, varscan2
- ARSL | c.1598T>C p.V533A | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101140804; called by muse, mutect2, varscan2
- ATAD2 | c.825T>A p.D275E | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149531312; called by muse, mutect2, varscan2
- BRINP1 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV99777104; called by muse, mutect2, varscan2
- C1orf226 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.202); catalogued as COSV100908207, COSV63397123; called by muse, mutect2
- CASP5 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.24); catalogued as rs767502229, COSV99508067, COSV99508154; called by muse, mutect2, varscan2
- CCDC146 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs560273200, COSV99593214; called by muse, mutect2, varscan2
- CTSG | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1252852506, COSV53535635, COSV99361719; called by muse, mutect2, varscan2
- CYP8B1 | c.1007A>G p.H336R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV100296324; called by muse, mutect2, varscan2
- DAPK1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs1320849258, COSV63787613; called by muse, mutect2, varscan2
- DHX30 | c.346G>A p.A116T (on ENST00000445061 / NM_138615.3; = p.A77T on NM_014966.3) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV100820130; called by muse, mutect2
- DNAH5 | c.2876T>C p.L959P | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV54241406; called by muse, mutect2, varscan2
- DOCK2 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV99915917; called by muse, varscan2
- FBXL18 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.607); catalogued as rs376586905; called by muse, mutect2, varscan2
- FLG | c.4615A>C p.S1539R | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs536230632, COSV100912077, COSV64237938; called by muse, mutect2, varscan2
- FZD3 | c.665T>C p.L222S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99528423; called by muse, mutect2, varscan2
- GAB4 | c.1676A>G p.Q559R | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV101272110; called by muse, mutect2, varscan2
- GPX4 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 91/102 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100685068; called by muse, mutect2, varscan2
- HSD17B4 | c.1843-1G>T p.X615_splice (on ENST00000414835 / NM_001199291.3; = p.X590_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99820226; called by muse, mutect2, varscan2
- IFNA8 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 86/128 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV101206944; called by muse, mutect2, varscan2
- IRX6 | c.723A>C p.E241D | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51859141; called by muse, varscan2
- KRT6B | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.07); catalogued as COSV99361065; called by muse, mutect2
- LAG3 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs752117712, COSV52569005; called by muse, mutect2, varscan2
- LINGO2 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431297; called by muse, mutect2, varscan2
- LPAR2 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99179652; called by mutect2, varscan2
- MAP1B | c.3866C>T p.S1289F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV99703001; called by muse, mutect2, varscan2
- MAPK11 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs202139039, COSV100404521, COSV100404561; called by muse, mutect2, varscan2
- MPP2 | c.1282C>T p.R428C (on ENST00000461854 / NM_001278372.2; = p.R404C on NM_005374.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs374234227; called by muse, mutect2, varscan2
- MUC16 | c.37007C>T p.T12336I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.792); catalogued as rs796971309, COSV67479248; called by muse, mutect2, varscan2
- MUC17 | c.9292T>G p.S3098A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV100075337; called by muse, mutect2, varscan2
- MYO3B | c.307T>C p.W103R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100512008; called by muse, mutect2, varscan2
- NLRP12 | c.3061C>T p.R1021W | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs774905024, COSV100146001; called by muse, mutect2, varscan2
- NSD2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100373988, COSV56398736; called by muse, mutect2, varscan2
- NUP54 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 51/56 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99345518; called by muse, mutect2, varscan2
- OPN4 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99618900; called by muse, mutect2, varscan2
- OR1A2 | c.668C>G p.T223R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV67936993; called by muse, mutect2, varscan2
- PHF20L1 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs201918932; called by muse, mutect2, varscan2
- PIWIL1 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99806990; called by muse, mutect2, varscan2
- PRG4 | c.4171C>A p.R1391S | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV100798340; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1894C>A p.P632T (on ENST00000352766; = p.P553T on NM_181334.5) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100424717; called by muse, mutect2, varscan2
- PRSS16 | c.1370C>A p.A457D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100042031; called by muse, mutect2, varscan2
- PTCH2 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV100942291; called by muse, mutect2, varscan2
- SHROOM2 | c.4099C>G p.L1367V | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); catalogued as COSV101099116; called by muse, mutect2, varscan2
- SLAMF6 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100924953; called by muse, mutect2, varscan2
- SLC5A7 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99886754; called by muse, mutect2, varscan2
- TEP1 | c.5003+1G>C p.X1668_splice | Splice Site (SNP) | VAF 32/54 reads (59%) | catalogued as COSV99403390; called by muse, mutect2, varscan2
- THSD7B | c.1492C>A p.H498N | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV55655652, COSV55684188; called by muse, mutect2, varscan2
- TMEM266 | c.739A>T p.R247W | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101189672; called by muse, mutect2, varscan2
- UNC79 | c.5900A>G p.Q1967R (on ENST00000393151 / NM_001346218.2; = p.Q1790R on NM_020818.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV99830071; called by muse, varscan2
- USP6 | c.3037-1G>A p.X1013_splice | Splice Site (SNP) | VAF 71/149 reads (48%) | catalogued as COSV100005075; called by muse, mutect2, varscan2
- WARS2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV52476147; called by muse, mutect2, varscan2
- YIPF4 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.538); catalogued as COSV99480098; called by muse, mutect2, varscan2
- ZMYM2 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); catalogued as COSV101244151; called by muse, mutect2, varscan2
- ZNF768 | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99411645; called by muse, mutect2, varscan2
- CNR1 | c.717G>A p.L239= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100759365; called by muse, mutect2, varscan2
- DLX3 | c.435G>A p.Q145= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101460586; called by muse, varscan2
- ECEL1 | c.531G>A p.Q177= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1221193069, COSV100459070; called by muse, mutect2, varscan2
- EVA1A | c.57C>T p.N19= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99285950; called by muse, mutect2, varscan2
- EXD2 | c.1824G>A p.L608= (on ENST00000312994 / NM_001193362.1; = p.L483= on NM_018199.3) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100474575, COSV57281703; called by muse, mutect2, varscan2
- GABRG1 | c.984T>G p.S328= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV54954145; called by muse, mutect2, varscan2
- HYDIN | c.876C>T p.A292= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- KMT2A | c.10266G>A p.A3422= | Silent (SNP) | VAF 17/18 reads (94%) | catalogued as rs782505642, COSV63281204; called by muse, mutect2, varscan2
- MPDZ | c.2985C>T p.V995= | Silent (SNP) | VAF 121/127 reads (95%) | catalogued as COSV100057742; called by muse, mutect2, varscan2
- OR6N1 | c.750C>T p.I250= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs770053604, COSV100625316; called by muse, mutect2, varscan2
- PRDM14 | c.465G>A p.A155= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as rs952295630, COSV99400582; called by muse, mutect2, varscan2
- RPTN | c.1707T>C p.Y569= | Silent (SNP) | VAF 26/247 reads (11%) | catalogued as rs1233702614, COSV100285855; called by muse, mutect2
- TLR10 | c.912G>A p.L304= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100458117; called by muse, mutect2, varscan2
- ZFP57 | c.1458T>C p.S486= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100971984; called by muse, mutect2, varscan2
